Surgical pathology report (de-identified scan), TCGA case TCGA-ZP-A9D4, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-ZP-A9D4-01A (Primary Tumor).

[page 1 of 4]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

Component

SURG PATH FINAL REPORT

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

A. Gallbladder

B. Liver FS

Clinical Notes:

Pre-op diagnosis: Liver tumor. B) Fresh tissue saved for
tissue bank.

Diagnosis:

A. Gallbladder, cholecystectomy:

- Gallbladder with no pathologic diagnosis.
- Negative for dysplasia or malignancy.

B. Liver, right hepatectomy:

- Hepatocellular carcinoma, well differentiated (9.5 cm).
- Parenchymal resection margin negative for malignancy.
- AJCC Stage (2010): pT1 pNX pMX.
- Please see Tumor Characteristics.

IMMUNOHISTOCHEMISTRY DISCLAIMER: This test was developed and its performance characteristics determined by

It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. By placing the electronic signature on this report, the pathologist certifies that all positive and negative immunohistochemistry controls were reviewed and approved.

(Electronically signed by)

Verified:

ICD O-3
Carcinoma, Hepatocellular NOS
8170/3
Site: Liver C22.0
AJ 2/3/14

[page 2 of 4]
[REDACTED]

Tumor Characteristics:
B: Liver, Resection (AJCC 7th Ed., 2010)
SPECIMEN TYPE:
Right lobectomy
TUMOR SIZE:
Greatest dimension: 9.5 cm
Additional dimensions: 9.0 x 8.2 cm

Accession #:

HISTOLOGIC TYPE:
Hepatocellular carcinoma
HISTOLOGIC GRADE:
GI: Well differentiated
PRIMARY TUMOR (pT):
pT1: Solitary tumor without vascular invasion
REGIONAL LYMPH NODES (pN):
pNX: Regional lymph nodes cannot be assessed
AJCC STAGING (pTNM):
pT1 pNX pMX
MARGINS:
Parenchymal margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 5.0
mm
LYMPH-VASCULAR INVASION:
Macroscopic Venous (Large Vessel) Invasion
Not identified
Microscopic (Small Vessel) Invasion
Not identified
ADDITIONAL PATHOLOGIC FINDINGS:
Hepatitis (specify type): Macrovesicular steatosis

Gross:

A. The specimen is labeled "gallbladder." Received in formalin is a gallbladder measuring 7.8 x 2.5 x 1.8 cm. The serosal surface of the gallbladder is tan-pink to purple, smooth, glistening. Focal areas of hemorrhage are noted on the serosal surface. The gallbladder is opened to reveal approximately 5 cc of dark green-brown liquid bile. The gallbladder mucosa is dark greenish-brown and velvety. No discrete nodules or lesions are grossly identified within the lumen of the gallbladder. No gallstones are present within the gallbladder. Representative sections, including the cystic duct margin, are submitted in cassette A.

B. The specimen is labeled "liver." Received fresh for frozen section is an 885 gram portion of liver, measuring 16.0 x 13.0 x 8.5 cm. The capsular surface of the liver exhibits a nodular appearance. The capsular surface is pink-red to light purple, and a mass is seen bulging under

[REDACTED]

[page 3 of 4]
[REDACTED]

the capsule. The parenchymal resection margin is marked with black ink, and the specimen is serially sectioned to reveal a 9.5 x 9.0 x 8.2 cm, relatively well-circumscribed, light greenish-brown to tan-white to focally hemorrhagic mass with variegated cut surface. The mass is located 0.5 cm from the closest parenchymal resection margin. Two representative sections of the mass are submitted for frozen section. The uninvolved liver parenchyma is dark reddish-

Accession #:

brown. No distinct nodularity is observed in the uninvolved liver parenchyma. No other distinct lesions or nodules are grossly identified. Gross photographs were taken. Representative sections are submitted as follows:

Cassette Designation:

B1-2	Frozen section remnants
B3-4	Mass with closest parenchymal
resection margin	
B5-8	Additional sections of the mass
B9	Uninvolved liver parenchyma

Intraoperative Consultation:

FROZEN SECTION:

B1-2. Grade 1 hepatocellular carcinoma.

Microscopic:

Histological examinations have been performed on specimens A and B.

B. Sections of the liver show a proliferation of hepatocytes arranged in cell plates that are three to five cell layers thick. The hepatocytes exhibit granular eosinophilic cytoplasm, round to slightly irregular nuclei, prominent nucleoli, and increased nuclear to cytoplasmic ratios. The cells exhibit moderate pleomorphism. Occasional dilated sinusoids are seen within the tumor. Focal pseudoacinar formation is observed. A reticulin stain highlights the thickened hepatocyte plate. Immunohistochemical staining shows that the tumor cells are focally positive for glypican-3. The parenchymal resection margin is uninvolved by the tumor. The surrounding uninvolved liver parenchyma is composed of hepatocytes in lobular configuration composed of cell plates that are one

[page 4 of 4]
[REDACTED]

to two cell layers thick. Mild macrovesicular steatosis is observed particularly around zone three. Focal mild periportal inflammation is observed. There is no evidence of regenerative nodule formation or bridging fibrosis in the uninvolved liver parenchyma.

Accession #:

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

[REDACTED]

Source: NCI Genomic Data Commons file 0dea5754-fd4a-4c04-8445-cd37c1affe61 (TCGA-ZP-A9D4.8BD8A06B-4C20-4EF9-950D-AFED27C1303F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).